Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7748, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7748-01A (Primary Tumor).

DIAGNOSIS

DIAGNOSIS:

A. Right pelvic lymph nodes; excision:

No metastatic carcinoma identified in ten lymph nodes (0/10).
Intraoperative consultation corroborated.

B. Prostate; radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 21 gm, 4.0 x 3.5 x 2.5 cm.
3. Tumor quantitation: Tumor occupies approximately 30% of the right side.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 6/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Suspicious for lymphovascular space invasion.
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Surgical margins including apex, base, and inked prostatic margin are negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes examined: Ten, see specimen A.
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/10).

Other:

1. pTNM stage: pT2 N0.
2. Perineural invasion present.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right pelvic lymph nodes with FS
- B. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two containers labeled with the patient's name

A. Additionally labeled right pelvic lymph nodes and contains a 7.5 x 4.0 x 2.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, multiple firm fatty nodules are identified consistent with possible lymph nodes. They range from 1.0 up to 2.5 cm in greatest dimension. Three representative sections are submitted for frozen section with the residual entirely resubmitted for permanent section in cassette A1 labeled **. All remaining possible lymphoid tissue is submitted in cassettes 2-8.**

B. Additionally labeled prostate and contains a 21 gram, 4.0 x 3.5 x 2.5 cm prostate received with attached bilateral adnexa which has overall dimensions of 2.5 x 2.4 x 1.0 cm. The capsule is pink-tan and shaggy. Specimen is inked as follows: right side blue and left side black. The base and

apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a pink-tan focally cystic focally indurated cut surface with periurethral nodularity. A discrete mass is not identified grossly. Representative sections are submitted in cassettes B1-18 labeled designated as follows: 1-right prostate/seminal vesicle junction; 2-left prostate/seminal vesicle junction; 3 and 4-apical margin, perpendicular; 5 and 6-base margin, perpendicular; 7-9-right anterior, apex to base; 10-12-right posterior, apex to base; 13-15-left anterior, apex to base; 16-18-left posterior, apex to base. Additionally, yellow green and blue cassette are submitted for Genomics research each labeled

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS A: No tumor identified in three lymph nodes (0/3) per

Source: NCI Genomic Data Commons file a241319d-4aaa-4f48-8617-d4424d618bed (TCGA-HC-7748.6516E000-DC8C-4715-A561-EE47A114AD23.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).